Gene-level copy-number profile of tumor specimen TCGA-18-3411-01A from TCGA case TCGA-18-3411, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.0 years (23,370 days).
Specimen TCGA-18-3411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.34576e6b-4833-4f90-97a0-3ffb0b2d249c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3411-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/183038d1-95f2-46f9-bf66-e0b3db17500a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 5,706; copy number 3: 12,136; copy number 4: 16,728; copy number 5: 10,966; copy number 6: 7,990; copy number 7: 3,363; copy number 8: 1,482; copy number 9: 813; copy number 10: 96; copy number 11: 369; copy number 12: 98; copy number 16: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3411-01A-01D-1969-01): tumor purity 0.53, ploidy 4.44, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,441 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,890,767–117,528,872, 104 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr1:238,238,943–248,919,946, 259 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr3:181,505,075–198,222,513, 397 genes, copy number 9–11 (broad region; genes not listed).
- chr4:39,698,109–39,977,956, 8 genes, copy number 9 (within-gene range 3–9): UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP, PDS5A, ELOCP33, RNA5SP159.
- chr4:47,914,142–48,269,838, 7 genes, copy number 11 (within-gene range 5–11): NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA.
- chr17:18,809,956–22,706,703, 198 genes, copy number 11 (broad region; genes not listed).
- chr19:13,731,760–15,498,956, 98 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr19:21,358,930–23,147,221, 89 genes, copy number 9–16 (broad region; genes not listed).
- chr19:28,394,851–31,655,461, 63 genes, copy number 9 (broad region; genes not listed).
- chr19:35,351,552–36,772,825, 96 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr19:54,379,489–55,932,336, 122 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
